Somatic mutation profile of cancer-model specimen HCM-BROD-0642-C43-85N (Adherent Cell Line, passage 12; aliquot HCM-BROD-0642-C43-85N-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0642-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 54.0 years (19,715 days).
Specimen HCM-BROD-0642-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b5bb07b-9a6f-4d1a-a9c9-9acca4b716ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0642-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0642-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/873324e4-e3e3-4455-8c7d-1f87c0516e1b

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Frame Shift Del 2, Splice Site 1, 3'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTPA | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 64/373 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397515524, CM981966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX53 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 52/526 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV60068486; called by muse, mutect2, varscan2
- EHBP1 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99860232; called by muse, mutect2
- GPR174 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 86/503 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768792809; called by muse, mutect2, varscan2
- MAP3K5 | c.2415+1G>A p.X805_splice | Splice Site (SNP) | VAF 18/159 reads (11%) | catalogued as rs573748521, COSV62889782; called by muse, mutect2, varscan2
- NLRP10 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 59/570 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.084); catalogued as rs758062487, COSV60779271; called by muse, mutect2, varscan2
- OR8K3 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 50/552 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.065); catalogued as rs761417566; called by muse, mutect2
- PHF3 | c.2981A>G p.N994S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs187803576; called by muse, mutect2, varscan2
- RIMS2 | c.2882G>A p.R961Q (on ENST00000666250 / NM_001348490.2; = p.R769Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); catalogued as rs368813886; called by muse, varscan2
- SCPEP1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 92/447 reads (21%) | catalogued as rs368874401; called by muse, mutect2, varscan2
- TGM1 | c.1418del p.G473Afs*15 | Frame Shift Del (DEL) | VAF 43/349 reads (12%) | catalogued as rs758030729; called by mutect2, pindel, varscan2
- TMA16 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs762386189; called by muse, mutect2, varscan2
- ZNF292 | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60538309; called by muse, mutect2
- AMER3 | c.1967G>A p.G656D | Missense Mutation (SNP) | VAF 27/635 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- ATG4A | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 26/847 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CR1 | c.5958del p.L1986Ffs*9 | Frame Shift Del (DEL) | VAF 33/374 reads (9%) | called by mutect2, pindel
- FAXC | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GSG1 | c.928G>A p.G310S (on ENST00000651961 / NM_001080555.4; = p.G274S on NM_153823.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- KCNIP3 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 15/410 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2
- KIDINS220 | c.3983T>A p.F1328Y | Missense Mutation (SNP) | VAF 15/409 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2
- OPHN1 | c.450C>G p.H150Q | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OR8J3 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PDS5B | c.3818A>T p.D1273V | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.545); called by muse, mutect2
- PDZD2 | c.5905C>T p.P1969S | Missense Mutation (SNP) | VAF 49/543 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLBD2 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 94/481 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARA | c.1231C>A p.H411N | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PPRC1 | c.4823A>G p.D1608G | Missense Mutation (SNP) | VAF 14/482 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2
- SNX18 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 51/512 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); called by muse, mutect2
- THSD4 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 17/400 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- TRIM67 | c.1944G>T p.K648N | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ARFGEF3 | c.2004G>A p.A668= | Silent (SNP) | VAF 70/440 reads (16%) | catalogued as rs765548132; called by muse, mutect2, varscan2
- ARHGEF28 | c.1035C>T p.F345= | Silent (SNP) | VAF 40/276 reads (14%) | catalogued as rs374033565; called by muse, mutect2, varscan2
- C6orf120 | c.285A>G p.Q95= | Silent (SNP) | VAF 78/724 reads (11%) | catalogued as rs775269048; called by muse, mutect2, varscan2
- CD300LF | c.489C>T p.F163= | Silent (SNP) | VAF 40/383 reads (10%) | catalogued as rs200130350; called by muse, mutect2, varscan2
- DEFB125 | c.348T>C p.N116= | Silent (SNP) | VAF 63/442 reads (14%) | catalogued as rs753566285; called by muse, mutect2, varscan2
- PPP1R37 | c.1326G>A p.A442= | Silent (SNP) | VAF 17/506 reads (3%) | called by muse, mutect2
- BID | c.362-656G>A | Intron (SNP) | VAF 16/484 reads (3%) | called by muse, mutect2
- RAB11FIP4 | c.*5270C>T | 3'UTR (SNP) | VAF 88/466 reads (19%) | called by muse, mutect2, varscan2
